Gene-level copy-number profile of tumor specimen TCGA-86-8585-01A from TCGA case TCGA-86-8585, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 57.3 years (20,918 days).
Specimen TCGA-86-8585-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.3b4c4b90-c658-45bf-b490-a21e52ce3854.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-8585-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a244cc49-9d6f-43c5-ac1f-de83af24ded7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7; copy number 2: 28,878; copy number 3: 13,343; copy number 4: 9,069; copy number 5: 5,084; copy number 6: 1,324; copy number 7: 1,698; copy number 8: 163; copy number 9: 109; copy number 10: 28; copy number 13: 29; copy number 15: 2; copy number 19: 4; copy number 20: 18; copy number 23: 63.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-8585-01A-11D-2389-01): tumor purity 0.29, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,522 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr2:27,889,941–28,338,901, 1 gene, copy number 6 (within-gene range 3–6): BABAM2.
- chr2:28,134,408–28,751,722, 13 genes, copy number 6 (within-gene range 3–6): AC096552.1, AC093690.1, RPL23AP34, FLJ31356, FOSL2, AC104695.3, AC104695.2, AC104695.1, PLB1, SNRPGP7, AC074011.1, RNA5SP89, AC092164.1.
- chr2:42,712,740–43,233,394, 15 genes, copy number 7: RNU6-137P, OXER1, HAAO, FTOP1, CHORDC1P1, AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580, AC010883.2, AC010883.3, ZFP36L2, LINC01126, AC010883.1.
- chr5:58,198–45,895,970, 710 genes, copy number 7 (broad region; genes not listed).
- chr6:105,679,378–164,009,980, 906 genes, copy number 6–23 (within-gene range 4–23) (broad region; genes not listed).
- chr8:35,862,123–145,066,685, 1,722 genes, copy number 5–13 (broad region; genes not listed).
- chr10:44,712–13,528,974, 236 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:66,767–6,851,292, 191 genes, copy number 5 (broad region; genes not listed).
- chr13:30,617,693–31,483,699, 17 genes, copy number 7: USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, AL158065.1, WDR95P, HSPH1, B3GLCT, ANKRD26P4, AL161616.2, AL161616.1.
- chr13:34,347,986–37,105,664, 36 genes, copy number 7: LINC02343, LINC00457, AL161716.1, GAMTP2, Metazoa_SRP, AL138690.1, NBEA, SCAND3P1, PHBP13, MAB21L1, AL390071.1, LINC00445, DCLK1, SOHLH2, CCDC169-SOHLH2, CCDC169, RNU6-71P, SPART, SPART-AS1, CCNA1, H2ACP1, SERTM1, GAPDHP34, TCEAL4P1, ARL2BPP3, NDE1P2, RFXAP, SMAD9, SMAD9-IT1, LAMTOR3P1, RPL29P28, EIF4A1P5, ALG5, EXOSC8, SUPT20H, CSNK1A1L.
- chr13:58,165,827–58,752,233, 6 genes, copy number 7: LINC02338, LINC00374, AL161423.1, RNY4P29, CTAGE16P, DNAJA1P1.
- chr13:67,326,177–76,014,501, 85 genes, copy number 6–20 (within-gene range 4–20) (broad region; genes not listed).
- chr14:24,399,003–42,703,655, 254 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr14:101,552,221–106,875,071, 347 genes, copy number 5 (broad region; genes not listed).
- chr16:25,691,959–26,137,685, 2 genes, copy number 5 (within-gene range 3–5): HS3ST4, AC093516.1.
- chr16:26,025,237–35,912,516, 526 genes, copy number 5 (broad region; genes not listed).
- chr16:51,354,456–62,037,035, 232 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr17:51,630,313–54,478,168, 15 genes, copy number 5 (within-gene range 3–5): CA10, AC002090.1, LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3.
- chr18:23,134,564–27,795,637, 84 genes, copy number 7 (broad region; genes not listed).
- chr18:27,954,519–27,963,687, 1 gene, copy number 7: AC110015.1.
- chr18:30,290,161–30,414,073, 1 gene, copy number 7 (within-gene range 2–7): AC115100.1.
- chr18:34,221,007–36,279,119, 43 genes, copy number 6: AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3.
- chr18:36,417,055–36,424,185, 1 gene, copy number 6: AC055840.1.
- chr20:45,551,153–64,313,132, 474 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
